Somatic mutation profile of tumor specimen 0DB980 from CCDI case PBBKTJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,190 days).
Specimen 0DB980: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac8d28ba-7be4-421f-93bf-1efb3ee1c767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB97M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae2acd74-7180-4cdd-bb03-eda5ad56ecd1

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 431/1091 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP11B1 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 62/1132 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs952727650; called by muse, mutect2
- DUSP6 | c.811T>G p.F271V | Missense Mutation (SNP) | VAF 26/846 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54378675; called by muse, mutect2
- APP | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 183/667 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HCN2 | c.2379G>A p.S793= | Silent (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- TESK2 | c.-16A>C | 5'UTR (SNP) | VAF 16/546 reads (3%) | called by muse, mutect2
